Surgical pathology report (de-identified scan), TCGA case TCGA-SN-A84Y, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site BLN - Baylor, specimen TCGA-SN-A84Y-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

PATHOLOGIC DIAGNOSIS

RIGHT TESTICLE, RIGHT RADICAL ORCHIECTOMY:

- MIXED GERM CELL TUMOR
- YOLK-SAC TUMOR, 50%; EMBRYONAL CARCINOMA, 50%; IMMATURE TERATOMA, LESS THAN 2%; ISOLATED SYNCYTIOTROPHOBLAST CELLS (SEE COMMENT)
- TUMOR SIZE: 4.5 CM
- MACROSCOPIC EXTENT OF TUMOR: CONFINED TO TESTIS
- LYMPHOVASCULAR INVASION: PRESENT
- SEE CAP SYNOPTIC REPORT

PATHOLOGIC STAGING:

Primary Tumor (pT): pT2

Regional Lymph Nodes (pN): pNX

Distant Metastasis (pM): Not applicable

path ICD-O-3
Carcinoma, embryonal NOS 9070/3
path Mixed germ cell tumor 9085/3
Site *path* testis NOS C62.9
path Testicle NOS C62.9
9/11/29/13

Staff Pathologist

Comment

Approximately equal portions of yolk sac tumor and embryonal carcinoma are present with a very small amount of immature teratoma (less than 2%) and isolated syncytiotrophoblast cells. The presence of intratubular germ cell neoplasia is supported by strong staining with CD117. The control is appropriate. Multiple foci of lymphovascular invasion are seen.

Intradepartmental consultation: has been consulted on representative sections and concurs with the interpretation.

Pertinent Clinical Information

History of testicular mass

Gross Description

Specimen Material: Testicle

Received in formalin labeled "TESTICLE" is an 80 gram testicle (7.5 x 4.5 x 2.5 cm) with attached spermatic cord (11.5 cm in length, 1.2 cm in diameter) and epididymis (4 x 1 x 0.7 cm). The spermatic cord margin is inked violet. The tunica vaginalis is inked black. The tunica albuginea is gray-white

[page 2 of 3]
and smooth. The opened testicle reveals a 4.5 x 4 cm well-circumscribed, bulging heterogeneous tan-white mass with hemorrhage which appears confined to the testis. The mass is located 2 cm from the tunica vaginalis and 0.8 cm from the tunica albuginea. Representative sections are submitted as follows: 1 upper spermatic cord margin
2 middle spermatic cord
3 distal spermatic cord
4 epididymis
5-6 mass and tunica albuginea
7-8 mass with tunica albuginea and epididymis
9-10 mass, tunica vaginalia and tunica albuginea
12-16 mass in relationship to tunica albuginea

Pathology Resident

Microscopic Description

CAP Synoptic Report:

Specimen Laterality: Right

Tumor Focality: Unifocal

Tumor Size: Greatest dimension of main tumor mass: 4.5 cm

Macroscopic Extent of Tumor: Confined to the testis

Histologic Type: Mixed germ cell tumor

Embryonal carcinoma, 50%

Yolk sac tumor, 50%

Teratoma, immature, less than 2%

Isolated syncytiotrophoblast cells

Margins: Spermatic Cord Margin: Negative

Microscopic Tumor Extension: None (spermatic cord, tunica vaginalis, scrotal wall)

Lymph-Vascular Invasion: Present

Pathologic Staging: Primary Tumor (pT): pT2

Regional Lymph Nodes (pN): pNX

Distant Metastasis (pM): Not applicable

The staff pathologist listed below has reviewed this case.

This immunohistochemistry test(s) was developed and its performance characteristics determined by the

and/or affiliated institution. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

*Per TSS, dx discrepancy from statlab
TCGA tumor to be embryonal, 100%.*

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Testicular Germ Cell Tumors - (Testicular Germ Cell Tumors)	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report YOLK-SAC TUMOR, 50%; EMBRYONAL CARCINOMA, 50%; IMMATURE TERATOMA, LESS THAN 2%;

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF EMBRYONAL CARCINOMA, 100%

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

The tissue collected for research was taken from an area that was primarily embryonal carcinoma.

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file 828ad840-fa03-4b37-93af-9124cdfc2ed9 (TCGA-SN-A84Y.B691EAED-C9C7-4437-92A5-7B37E9544AA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).